Gene-level copy-number profile of tumor specimen TCGA-23-2647-01A from TCGA case TCGA-23-2647, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 49.8 years (18,205 days).
Specimen TCGA-23-2647-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.246c6949-4565-4f69-8744-02e05764a274.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-23-2647-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate.
https://portal.gdc.cancer.gov/files/65c7e952-a25e-4b45-9eca-3506f1225e7d

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 2; copy number 2: 10,410; copy number 3: 11,321; copy number 4: 28,741; copy number 5: 5,648; copy number 6: 2,022; copy number 7: 957; copy number 8: 704; copy number 9: 1; copy number 10: 3; copy number 13: 3.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:190,830,965–190,832,173, 1 gene: AC092952.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 7 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:40,900,016–40,901,854, 1 gene, copy number 9: AC048387.1.
- chr8:121,612,116–121,994,185, 3 genes, copy number 13 (within-gene range 8–13): HAS2, HAS2-AS1, LINC02855.
- chr12:85,781,892–85,882,992, 3 genes, copy number 10: AC137768.1, RASSF9, NTS.

Autosomal genes at a single copy (total copy number 1): 2. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
